TARGET case TARGET-50-PAJLZN — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d68b4e9-86de-5581-b58a-1170161cde0c

Demographics
Sex at birth: male; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 2.7 years (1,004 days); Year of diagnosis: 1997; Days to last follow up: 2,868 days (7.9 years); Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 244 days; Days to first event: 244 days; First event: Relapse.
- Days to follow up: 2,868 days (7.9 years); Year of follow up: 2011.

Biospecimens (1 sample)
- Sample TARGET-50-PAJLZN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJLZN-01A:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: Yes
- % Tumor Nuclei: Top: 98
- % Non tumor Nuclei: Top: 2
- % Cellular Tumor: Top: 100
- % Normal: Top: 0
- % Stroma: Top: 0
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 95
- % Non tumor Nuclei: Bottom: 5
- % Cellular Tumor: Bottom: 95
- % Normal: Bottom: 0
- % Stroma: Bottom: 5
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: Pass

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJLZN-01A-02:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 99
- % Non tumor Nuclei: Top: 1
- % Cellular Tumor: Top: 98
- % Normal: Top: 0
- % Stroma: Top: 2
- % Necrosis: Top: 0
- % Tumor Nuclei: Bottom: 98
- % Non tumor Nuclei: Bottom: 2
- % Cellular Tumor: Bottom: 95
- % Normal: Bottom: 0
- % Stroma: Bottom: 5
- % Necrosis: Bottom: 0
- Pathology Pass/Fail: pass

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2868
- Stage: IV
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT
